Somatic mutation profile of tumor specimen TCGA-UZ-A9PZ-01A (aliquot TCGA-UZ-A9PZ-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9PZ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III.
Specimen TCGA-UZ-A9PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4fa0c68-2568-4532-99e2-b971598b23c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9PZ-10A (Blood Derived Normal), aliquot TCGA-UZ-A9PZ-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/12c3bdf1-3a36-4559-95ce-b0ad01aa8382

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 31, Silent 14, Frame Shift Del 3, Nonsense Mutation 3, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AQP1 | c.742G>A p.G248S | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs149637560; called by muse, mutect2, varscan2
- BMP7 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV101215843; called by muse, mutect2, varscan2
- CUBN | c.8471A>G p.N2824S | Missense Mutation (SNP) | VAF 74/91 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as rs141773881; called by muse, mutect2, varscan2
- DIAPH1 | c.1723T>C p.S575P | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1374199986, COSV99526331; called by muse, mutect2, varscan2
- DSG1 | c.3141T>A p.Y1047* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV99935807; called by muse, mutect2, varscan2
- DST | c.10993G>C p.G3665R (on ENST00000361203 / NM_001374722.1; = p.G1253R on NM_015548.5) | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.749); catalogued as COSV99754186; called by muse, mutect2, varscan2
- FAR1 | c.532A>C p.I178L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100701546; called by muse, mutect2, varscan2
- GPR155 | c.2209G>C p.E737Q | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as COSV99789804; called by muse, mutect2, varscan2
- GREB1 | c.3244G>A p.A1082T | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV52192506, COSV99302723; called by muse, mutect2, varscan2
- GRIA2 | c.1647C>A p.C549* | Nonsense Mutation (SNP) | VAF 39/124 reads (31%) | catalogued as COSV52385622, COSV99643936; called by muse, mutect2, varscan2
- ICE1 | c.5578A>T p.R1860W | Missense Mutation (SNP) | VAF 102/217 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV99664389; called by muse, mutect2, varscan2
- IGF2BP3 | c.1383G>T p.E461D | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as COSV99325261; called by muse, mutect2, varscan2
- KCTD8 | c.294C>A p.F98L | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100759429; called by muse, mutect2
- LRPAP1 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 41/95 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.216); catalogued as rs539416757, COSV56345632, COSV99578864; called by muse, mutect2, varscan2
- LRRC66 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.151); catalogued as COSV100602922; called by muse, mutect2, varscan2
- MYCBP2 | c.10817A>C p.E3606A (on ENST00000357337; = p.E3644A on NM_015057.5) | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100629945; called by muse, mutect2, varscan2
- NABP2 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV99910436; called by muse, mutect2, varscan2
- NAT8 | c.301T>C p.Y101H | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99721932; called by muse, mutect2, varscan2
- NLRP14 | c.1028T>A p.F343Y | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100204821; called by muse, mutect2, varscan2
- PEX2 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 33/98 reads (34%) | catalogued as CM111136, COSV100824755; called by muse, mutect2, varscan2
- PKHD1 | c.3500T>C p.L1167P | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV61890887; called by muse, mutect2, varscan2
- RASA1 | c.1502A>G p.D501G | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99169728; called by muse, mutect2, varscan2
- RXFP3 | c.880A>T p.I294F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100347473; called by muse, mutect2, varscan2
- SHMT1 | c.1202T>C p.L401P | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100363512; called by muse, mutect2, varscan2
- SLC1A5 | c.1517C>G p.P506R | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.168); catalogued as COSV101314769; called by muse, mutect2, varscan2
- SLC25A13 | c.1916del p.G639Afs*61 | Frame Shift Del (DEL) | VAF 79/201 reads (39%) | catalogued as rs1562773708; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SLC7A2 | c.943C>T p.P315S (on ENST00000494857 / NM_001370338.1; = p.P355S on NM_003046.6) | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99134615; called by muse, mutect2, varscan2
- TBCD | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164127534, COSV100333255, COSV56182069; called by muse, mutect2, varscan2
- TENM3 | c.5131G>A p.G1711S | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101305028; called by muse, mutect2, varscan2
- TSPAN11 | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99666827; called by muse, mutect2
- VPS36 | c.843G>T p.L281F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100955169; called by muse, mutect2, varscan2
- ZBTB24 | c.1235A>C p.H412P | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.174); catalogued as COSV100018403; called by muse, mutect2, varscan2
- ZFC3H1 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.7); PolyPhen benign (0.227); catalogued as COSV100350408; called by muse, varscan2
- ZNF429 | c.128T>A p.L43Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100641848; called by muse, mutect2, varscan2
- ZNF622 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs953136844, COSV58075017; called by muse, mutect2, varscan2
- HSPD1 | c.183_184del p.V62Dfs*3 | Frame Shift Del (DEL) | VAF 43/145 reads (30%) | called by mutect2, pindel, varscan2
- KRTAP10-7 | c.162C>G p.S54R | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- LRRC42 | c.1201del p.T401Qfs*25 | Frame Shift Del (DEL) | VAF 46/112 reads (41%) | called by mutect2, pindel*, varscan2
- ATP1A4 | c.2518A>C p.R840= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as COSV100927503; called by muse, mutect2, varscan2
- C8orf74 | c.429G>A p.E143= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100261876; called by muse, mutect2, varscan2
- CNNM3 | c.1353C>T p.D451= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs201161789; called by muse, mutect2, varscan2
- GIGYF2 | c.112T>C p.L38= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as COSV101004240; called by muse, mutect2, varscan2
- HELZ2 | c.4944C>T p.G1648= (on ENST00000467148 / NM_001037335.2; = p.G1079= on NM_033405.3) | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as COSV101427547; called by muse, mutect2, varscan2
- KCNH5 | c.396G>A p.T132= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs143574473; called by muse, mutect2, varscan2
- LRRC66 | c.1626G>C p.V542= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as COSV100602923; called by muse, mutect2, varscan2
- MUTYH | c.1158G>A p.L386= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV100587999; called by muse, mutect2, varscan2
- MYCBP2 | c.10818A>G p.E3606= (on ENST00000357337; = p.E3644= on NM_015057.5) | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs1258339328, COSV100629942; called by muse, mutect2, varscan2
- PHF2 | c.2433G>C p.L811= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as rs751469501, COSV100823110; called by muse, mutect2, varscan2
- PIH1D1 | c.543G>A p.S181= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV51806467; called by muse, mutect2, varscan2
- SCTR | c.621C>T p.Y207= | Silent (SNP) | VAF 35/92 reads (38%) | catalogued as COSV99191554; called by muse, mutect2, varscan2
- SLC28A1 | c.1884A>G p.P628= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as COSV99722871; called by muse, mutect2, varscan2
- SLC50A1 | c.366T>C p.P122= | Silent (SNP) | VAF 22/40 reads (55%) | catalogued as COSV100310289; called by muse, mutect2, varscan2
